Gene-level copy-number profile of tumor specimen TCGA-3A-A9I5-01A from TCGA case TCGA-3A-A9I5, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; Tumor grade: G1; Age at diagnosis: 58.0 years (21,175 days).
Specimen TCGA-3A-A9I5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.67bc13e7-99d1-41e3-94d1-95967ecdf630.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3A-A9I5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0485ff8f-300e-4451-9b0f-888d3634c048

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 310; copy number 1: 12,166; copy number 2: 40,680; copy number 3: 3,380; copy number 4: 2,779; copy number 5: 402; copy number 7: 103.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3A-A9I5-01A-11D-A38F-01): tumor purity 0.33, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 310 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:173,094,868–190,092,279, 262 genes (broad region; genes not listed).
- chr8:150,584–2,165,552, 48 genes (within-gene range 0–1): AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 505 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:148,923,639–150,113,372, 41 genes, copy number 5 (within-gene range 3–5): SH3TC2, AC116312.1, RNU6-732P, MIR584, SH3TC2-DT, RN7SKP145, ABLIM3, AC012613.1, AC012613.2, AFAP1L1, AC131025.3, GRPEL2, GRPEL2-AS1, PCYOX1L, IL17B, AC131025.1, CARMN, AC131025.2, MIR143, MIR145, CSNK1A1, AC021078.1, RPL29P14, ARHGEF37, RNU6-588P, AC022100.1, U3, RN7SL868P, PPARGC1B, MIR378A, PDE6A, MFFP2, Y_RNA, SLC26A2, TIGD6, HMGXB3, AC011406.1, RPS20P4, CSF1R, RPL7P1, Y_RNA.
- chr17:58,755,854–75,708,062, 464 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,745. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
